Somatic mutation profile of tumor specimen TCGA-HW-8322-01A (aliquot TCGA-HW-8322-01A-11D-2395-08) from TCGA case TCGA-HW-8322, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.8 years (14,548 days).
Specimen TCGA-HW-8322-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f16652c8-fca1-415f-a2fc-1e4bacf2049b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-8322-10A (Blood Derived Normal), aliquot TCGA-HW-8322-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612a3406-4f9d-404a-a9b4-94b10f5c87e2

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Frame Shift Del 3, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- ADSS1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs999498738, COSV58276014; called by muse, mutect2, varscan2
- APOL1 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as COSV59869773; called by muse, mutect2, varscan2
- ARL6 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60118801; called by muse, mutect2
- BRAP | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV59538356; called by muse, mutect2, varscan2
- KCNN2 | c.415C>T p.L139F (on ENST00000264773; = p.L351F on NM_021614.4) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53297733; called by muse, mutect2, varscan2
- KCNT2 | c.2782A>G p.M928V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV54105365; called by muse, mutect2, varscan2
- METTL16 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV54015978; called by muse, mutect2, varscan2
- MIA3 | c.3184C>T p.H1062Y | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV60517096; called by muse, mutect2, varscan2
- MYH3 | c.4616C>G p.A1539G | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56869453; called by muse, mutect2
- RAD17 | c.1268T>C p.L423S (on ENST00000380774 / NM_133339.2; = p.L412S on NM_002873.1) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51459417; called by muse, mutect2, varscan2
- RBFOX1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60946461, COSV60979056; called by muse, mutect2, varscan2
- REC8 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759974100, COSV61018163; called by muse, mutect2, varscan2
- ROBO1 | c.3185G>A p.R1062H | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.731); catalogued as rs770855014, COSV71392052; called by muse, mutect2, varscan2
- TAS1R3 | c.1006del p.Q336Sfs*3 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs780143467; called by mutect2, pindel, varscan2
- TFPT | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs201891249; called by muse, mutect2, varscan2
- NEU2 | c.288dup p.T97Dfs*35 | Frame Shift Ins (INS) | VAF 30/175 reads (17%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.6211_6223del p.E2071Rfs*36 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- NOTCH1 | c.4500del p.F1500Lfs*80 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- GIPC1 | c.462C>T p.Y154= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as rs1454872189, COSV61774500; called by muse, mutect2, varscan2
- RHEX | c.54C>T p.S18= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV58981862; called by muse, mutect2, varscan2
- SERPINE1 | c.1023G>A p.A341= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs765004033, COSV56171238; called by muse, mutect2, varscan2
